Gene-level copy-number profile of tumor specimen ALCH-B3I9-TTP1-A from ALCHEMIST case ALCH-B3I9, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 59.2 years (21,631 days).
Specimen ALCH-B3I9-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 83045081-d8a9-41db-904c-d6f1b57954eb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3I9-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,217 have no estimate.
https://portal.gdc.cancer.gov/files/e5ca0f34-bcc5-40b5-859c-b561f9e48962

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 492; copy number 2: 54,214; copy number 3: 3,581; copy number 4: 103.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:165,007,086–165,060,554, 8 genes: AC106872.9, AC106872.8, AC106872.2, TRIM60, AC106872.11, AC106872.7, AC106872.6, TRIM75P.
- chr6:17,381,367–17,382,120, 1 gene: AL034372.1.
- chr9:61,581,813–61,582,675, 1 gene: AL935212.3.
- chr16:8,847,650–8,870,032, 5 genes (within-gene range 0–2): AC012173.1, AC022167.2, CARHSP1, AC022167.1, AC022167.4.
- chr16:68,367,325–68,370,262, 1 gene (within-gene range 0–1): AC099521.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 492. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
